Gene-level copy-number profile of tumor specimen TCGA-EA-A556-01A from TCGA case TCGA-EA-A556, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 38.3 years (13,988 days).
Specimen TCGA-EA-A556-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.0e4b81af-7030-46a8-8b18-8a432f331280.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A556-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3938199b-08b7-4ddd-b633-526baa11d13d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 5,373; copy number 3: 10,005; copy number 4: 34,712; copy number 5: 5,777; copy number 6: 2,350; copy number 7: 306; copy number 8: 1,041; copy number 10: 154; copy number 14: 13; copy number 21: 67; copy number 25: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A556-01A-11D-A26F-01): tumor purity 0.7, ploidy 3.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 245 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,604,856–34,039,104, 1 gene, copy number 25 (within-gene range 2–25): AF279873.3.
- chr8:33,859,480–43,674,591, 202 genes, copy number 10–25 (broad region; genes not listed).
- chr8:119,873,717–120,373,573, 4 genes, copy number 10 (within-gene range 6–10): DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr14:21,351,476–21,673,818, 24 genes, copy number 10 (within-gene range 7–10): SUPT16H, AL135744.1, CHD8, SNORD9, SNORD8, AL161747.1, EIF4EBP1P1, RN7SL650P, RAB2B, TOX4, METTL3, SALL2, AL161747.2, RBBP4P5, OR10G3, AC243972.2, OR10G1P, UBE2NP1, TRAV1-1, OR10G2, TRAV1-2, ARL6IP1P1, OR4E2, OR4E1.
- chr17:80,260,866–80,542,605, 13 genes, copy number 10 (within-gene range 5–10): RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31.
- chr17:80,602,549–80,602,926, 1 gene, copy number 10: RPL31P7.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
